Somatic mutation profile of tumor specimen 0DIMWU from CCDI case PBBVUP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead.
Specimen 0DIMWU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f19ce5e6-64d6-42cf-a1a6-873e70ea15be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIMWR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d329b48-bf46-40ef-8628-8df459e82880

The open-access MAF lists 77 somatic variants for this specimen: 40 protein-altering or splice-affecting, 18 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 18, Intron 9, 3'UTR 6, Nonsense Mutation 4, Splice Site 3, 5'UTR 3, Frame Shift Del 3, In Frame Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 183/339 reads (54%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APBB1IP | c.807C>A p.N269K | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV63076746; called by muse, mutect2, varscan2
- ATP6V1C2 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 102/676 reads (15%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as rs184895235; called by muse, mutect2, varscan2
- CEP126 | c.3187T>C p.S1063P | Missense Mutation (SNP) | VAF 20/499 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as rs1212195539; called by muse, mutect2
- EIF4E2 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 115/848 reads (14%) | catalogued as rs370171571; called by muse, mutect2, varscan2
- FADS1 | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 131/376 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs1403644751; called by muse, mutect2, varscan2
- FGD2 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 115/518 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs747641806, COSV51465153; called by muse, mutect2, varscan2
- GPC3 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 18/644 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV100892675; called by muse, mutect2
- IL4R | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 224/590 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs1246781172; called by muse, mutect2, varscan2
- NBPF9 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.934); catalogued as rs1478621870, COSV58398634; called by muse, mutect2, varscan2
- PDCD11 | c.1178A>T p.Y393F | Missense Mutation (SNP) | VAF 17/492 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1283252992; called by muse, mutect2
- SIGLEC16 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 104/605 reads (17%) | catalogued as rs756035566; called by muse, mutect2, varscan2
- ACRBP | c.33_36del p.L12* | Frame Shift Del (DEL) | VAF 57/324 reads (18%) | called by mutect2, pindel, varscan2
- AHCTF1 | c.869+2T>C p.X290_splice (on ENST00000366508; = p.X264_splice on NM_015446.5) | Splice Site (SNP) | VAF 15/399 reads (4%) | called by muse, mutect2
- AP2B1 | c.2634G>T p.K878N | Missense Mutation (SNP) | VAF 32/722 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); called by muse, mutect2
- C1QTNF1 | c.34T>C p.Y12H | Missense Mutation (SNP) | VAF 40/910 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); called by muse, mutect2
- DDX43 | c.1337_1343del p.M446Tfs*8 | Frame Shift Del (DEL) | VAF 65/305 reads (21%) | called by mutect2, pindel, varscan2
- DNAH5 | c.7504C>T p.R2502C | Missense Mutation (SNP) | VAF 230/609 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EML6 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 146/589 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ERICH6 | c.706A>T p.R236* | Nonsense Mutation (SNP) | VAF 88/457 reads (19%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.1434A>T p.E478D | Missense Mutation (SNP) | VAF 228/450 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HAUS1 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.232); called by muse, mutect2
- HMGB4 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 249/781 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- IRAG2 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 119/314 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPRID2 | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 234/703 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MAN1C1 | c.921C>A p.S307R | Missense Mutation (SNP) | VAF 27/833 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- MCAT | c.604T>G p.S202A | Missense Mutation (SNP) | VAF 273/481 reads (57%) | SIFT tolerated (0.68); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MTREX | c.1716C>G p.N572K | Missense Mutation (SNP) | VAF 144/284 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- NCKIPSD | c.1816C>T p.H606Y | Missense Mutation (SNP) | VAF 18/532 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- NEGR1 | c.718A>T p.S240C | Missense Mutation (SNP) | VAF 95/586 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NOS2 | c.2209C>T p.L737F | Missense Mutation (SNP) | VAF 58/332 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- OR51A4 | c.835A>G p.N279D | Missense Mutation (SNP) | VAF 316/987 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5A1 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 167/556 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PCK1 | c.798+1G>T p.X266_splice | Splice Site (SNP) | VAF 36/620 reads (6%) | called by muse, mutect2
- PSMA2 | c.469_480del p.A157_A160del | In Frame Del (DEL) | VAF 77/357 reads (22%) | called by mutect2, pindel, varscan2
- RABEP2 | c.351del p.K118Rfs*8 | Frame Shift Del (DEL) | VAF 354/1061 reads (33%) | called by mutect2, pindel, varscan2
- RFX7 | c.2243_2248del p.N748_Q749del (on ENST00000559447 / NM_001368074.1; = p.N845_Q846del on NM_022841.7 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 101/361 reads (28%) | called by mutect2, pindel, varscan2
- THAP3 | c.46_74+9del p.X16_splice | Splice Site (DEL) | VAF 99/496 reads (20%) | called by mutect2, pindel, varscan2
- UGT2B10 | c.964G>C p.V322L | Missense Mutation (SNP) | VAF 22/860 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- ZNF697 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 34/820 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.68); called by muse, mutect2
- AL592490.1 | c.1377A>C p.P459= | Silent (SNP) | VAF 149/316 reads (47%) | called by muse, mutect2, varscan2
- APBB1IP | c.1920C>G p.P640= | Silent (SNP) | VAF 156/790 reads (20%) | catalogued as COSV66130472; called by muse, mutect2, varscan2
- CTSK | c.846A>G p.G282= | Silent (SNP) | VAF 175/585 reads (30%) | catalogued as rs150434921; called by muse, mutect2, varscan2
- CTSS | c.195G>A p.E65= | Silent (SNP) | VAF 105/699 reads (15%) | called by muse, mutect2, varscan2
- GABRA5 | c.1116G>A p.K372= | Silent (SNP) | VAF 208/627 reads (33%) | called by muse, mutect2, varscan2
- ITIH1 | c.639G>A p.P213= | Silent (SNP) | VAF 41/374 reads (11%) | catalogued as rs754271106, COSV56253723; called by muse, mutect2, varscan2
- KIF19 | c.595C>T p.L199= | Silent (SNP) | VAF 121/616 reads (20%) | called by muse, mutect2, varscan2
- MAGEB18 | c.997A>C p.R333= | Silent (SNP) | VAF 40/532 reads (8%) | called by muse, mutect2
- MED13 | c.6330C>T p.D2110= | Silent (SNP) | VAF 60/433 reads (14%) | catalogued as rs767087322; called by muse, mutect2, varscan2
- ODC1 | c.33C>T p.C11= | Silent (SNP) | VAF 204/580 reads (35%) | called by muse, mutect2, varscan2
- OR4C13 | c.591T>A p.I197= | Silent (SNP) | VAF 54/634 reads (9%) | called by muse, mutect2
- P2RY6 | c.714C>T p.A238= | Silent (SNP) | VAF 239/810 reads (30%) | catalogued as COSV100574002; called by muse, mutect2, varscan2
- PLCD3 | c.873C>T p.R291= | Silent (SNP) | VAF 98/686 reads (14%) | catalogued as rs776787815, COSV59560704; called by muse, mutect2, varscan2
- RRAGC | c.636T>C p.H212= | Silent (SNP) | VAF 128/418 reads (31%) | called by muse, mutect2, varscan2
- SPACA3 | c.303C>T p.D101= | Silent (SNP) | VAF 185/498 reads (37%) | called by muse, mutect2, varscan2
- SPEG | c.4452C>T p.A1484= | Silent (SNP) | VAF 200/525 reads (38%) | called by muse, mutect2, varscan2
- SYNE2 | c.6489G>A p.K2163= | Silent (SNP) | VAF 16/388 reads (4%) | called by muse, mutect2
- ZBTB46 | c.345G>A p.T115= | Silent (SNP) | VAF 186/618 reads (30%) | catalogued as rs1279098300, COSV55509249; called by muse, varscan2
- APRT | c.*21A>G | 3'UTR (SNP) | VAF 301/750 reads (40%) | catalogued as rs751125608; called by muse, mutect2, varscan2
- CDH15 | c.663+34C>T | Intron (SNP) | VAF 164/460 reads (36%) | catalogued as rs749029884; called by muse, mutect2, varscan2
- CDH5 | c.-19-34G>A | Intron (SNP) | VAF 76/176 reads (43%) | called by muse, mutect2
- COL8A2 | c.*76C>T | 3'UTR (SNP) | VAF 46/108 reads (43%) | called by muse, mutect2, varscan2
- CSH2 | c.456+84T>C | Intron (SNP) | VAF 232/709 reads (33%) | catalogued as rs759198862; called by muse, mutect2, varscan2
- DCLK2 | c.*85del | 3'UTR (DEL) | VAF 52/133 reads (39%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.*6T>C | 3'UTR (SNP) | VAF 159/349 reads (46%) | catalogued as rs201172648; called by muse, mutect2, varscan2
- ECHDC2 | c.801+92C>G | Intron (SNP) | VAF 56/155 reads (36%) | called by mutect2, varscan2
- EIF4E | c.*2147T>C | 3'UTR (SNP) | VAF 41/118 reads (35%) | called by muse, mutect2
- GBGT1 | c.360-41G>A | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- GGACT | c.-222-3740dup | Intron (INS) | VAF 87/449 reads (19%) | called by mutect2, pindel, varscan2
- HMGA2 | c.282+889A>T | Intron (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- HSPA6 | c.-43del | 5'UTR (DEL) | VAF 26/54 reads (48%) | called by mutect2, varscan2
- KCNQ3 | c.-39G>T | 5'UTR (SNP) | VAF 72/204 reads (35%) | called by muse, mutect2, varscan2
- MINDY4B | c.1060-66G>A | Intron (SNP) | VAF 39/64 reads (61%) | catalogued as rs1023213646; called by muse, mutect2, varscan2
- NTRK1 | c.1501+66_1501+67insATGT | Intron (INS) | VAF 89/378 reads (24%) | called by pindel, varscan2
- OR56B4 | c.-19A>G | 5'UTR (SNP) | VAF 16/126 reads (13%) | called by muse, varscan2
- TIGIT | chr3:114293953 CGAGACCGTCTTTTCTCAGAGGCTCAG>GAGAC | 5'Flank (DEL) | VAF 25/81 reads (31%) | called by pindel, varscan2*
- WNT5B | c.*22C>T | 3'UTR (SNP) | VAF 87/247 reads (35%) | called by muse, mutect2, varscan2
